Somatic mutation profile of tumor specimen C3L-03744-71 (aliquot CPT0216920011) from CPTAC case C3L-03744, project CPTAC-3 (Brain — Gliomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 75.4 years (27,552 days).
Specimen C3L-03744-71: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Brain; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) dd78d4fd-8291-43be-b1ba-055d1dc9a384.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-03744-31 (Blood Derived Normal), aliquot CPT0217940002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/da9833db-156f-4d30-abe5-4447d1324cbb

The open-access MAF lists 65 somatic variants for this specimen: 44 protein-altering or splice-affecting, 11 silent, 10 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 35, Silent 11, Intron 5, Splice Region 3, Frame Shift Del 3, Frame Shift Ins 2, RNA 2, 5'UTR 1, Nonsense Mutation 1, 5'Flank 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1525G>A p.G509R (on ENST00000288602 / NM_001374244.1; = p.G469R on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 63/633 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as rs121913357, BM1457681, COSV56070557, COSV56082352, COSV99953015; ClinVar: likely pathogenic; called by muse, mutect2
- CDH23 | c.6049G>A p.G2017S | Missense Mutation (SNP) | VAF 51/120 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.843); catalogued as rs183431253, CM077923, CS064378; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- NF1 | c.3739_3742del p.F1247Ifs*18 | Frame Shift Del (DEL) | VAF 108/255 reads (42%) | catalogued as rs1064794276; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- TP53 | c.746G>A p.R249K | Missense Mutation (SNP) | VAF 89/445 reads (20%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.918); catalogued as rs587782329, COSV52666526, COSV52668050, COSV52697169, COSV52713804; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- AC011005.1 | c.236C>T p.A79V | Missense Mutation (SNP) | VAF 43/757 reads (6%) | SIFT deleterious (0.05); PolyPhen benign (0.287); catalogued as rs748622301, COSV71956032; called by muse, mutect2
- ANXA6 | c.634C>T p.R212W | Missense Mutation (SNP) | VAF 67/198 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.939); catalogued as rs1386905312; called by muse, mutect2, varscan2
- ATP2B4 | c.1099G>A p.G367S | Missense Mutation (SNP) | VAF 12/98 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.936); catalogued as COSV100397582, COSV104415495; called by muse, mutect2, varscan2
- BRF1 | c.781C>T p.R261W | Missense Mutation (SNP) | VAF 53/163 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs781426397, COSV59268529; called by muse, mutect2, varscan2
- BTNL9 | c.778G>A p.V260I | Missense Mutation (SNP) | VAF 61/593 reads (10%) | SIFT tolerated (0.53); PolyPhen benign (0.001); catalogued as rs1378135353; called by muse, mutect2, varscan2
- CMYA5 | c.9832G>A p.A3278T | Missense Mutation (SNP) | VAF 33/111 reads (30%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.454); catalogued as COSV71406339, COSV71408483; called by muse, mutect2, varscan2
- FOXO1 | c.641G>A p.R214H | Missense Mutation (SNP) | VAF 17/59 reads (29%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.994); catalogued as COSV65428315; called by muse, mutect2, varscan2
- KIF27 | c.2815C>T p.R939C | Missense Mutation (SNP) | VAF 23/224 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.826); catalogued as rs3199677; called by muse, mutect2, varscan2
- KLF15 | c.134A>G p.D45G | Missense Mutation (SNP) | VAF 62/246 reads (25%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.828); catalogued as rs1157099763; called by muse, mutect2, varscan2
- KRTAP20-2 | c.58G>A p.G20S | Missense Mutation (SNP) | VAF 138/595 reads (23%) | PolyPhen benign (0.003); catalogued as rs1426063734, COSV58183402; called by muse, mutect2, varscan2
- MITD1 | c.655-7_655-3del | Splice Region (DEL) | VAF 18/49 reads (37%) | catalogued as rs755062358; called by mutect2, pindel, varscan2
- MTUS2 | c.2762G>A p.R921H | Missense Mutation (SNP) | VAF 22/70 reads (31%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.992); catalogued as rs989808191, COSV54991361; called by muse, mutect2, varscan2
- NPAS3 | c.647dup p.G217Wfs*11 (on ENST00000356141 / NM_001164749.2; = p.G185Wfs*11 on NM_022123.3) | Frame Shift Ins (INS) | VAF 44/237 reads (19%) | catalogued as rs1280227033; called by mutect2, pindel, varscan2
- PIWIL1 | c.2110G>A p.V704I | Missense Mutation (SNP) | VAF 56/349 reads (16%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.523); catalogued as rs1349757140, COSV55343819; called by muse, mutect2, varscan2
- PRAMEF14 | c.1188C>A p.D396E | Missense Mutation (SNP) | VAF 285/943 reads (30%) | SIFT tolerated (0.14); PolyPhen benign (0.015); catalogued as rs1186942967; called by muse, mutect2, varscan2
- TERB1 | c.566A>G p.N189S | Missense Mutation (SNP) | VAF 23/106 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs748282425; called by muse, mutect2, varscan2
- TMPRSS3 | c.1160C>T p.A387V | Missense Mutation (SNP) | VAF 125/733 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs201172277, COSV52305912; called by muse, mutect2, varscan2
- TP53BP2 | c.428G>A p.R143H (on ENST00000343537 / NM_001031685.3; = p.R14H on NM_005426.2) | Missense Mutation (SNP) | VAF 77/290 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs766049032, COSV100636849; called by muse, mutect2, varscan2
- YY1 | c.1106A>G p.N369S | Missense Mutation (SNP) | VAF 137/424 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV51760809; called by muse, mutect2, varscan2
- ZAR1L | c.511C>T p.R171W | Missense Mutation (SNP) | VAF 104/380 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.17); catalogued as rs1226281109; called by muse, mutect2, varscan2
- ARID4A | c.2218del p.S740Lfs*5 | Frame Shift Del (DEL) | VAF 18/48 reads (38%) | called by mutect2, varscan2
- CACNA1B | c.937A>G p.M313V | Missense Mutation (SNP) | VAF 65/163 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- CRYZL1 | c.865G>A p.V289I | Missense Mutation (SNP) | VAF 41/228 reads (18%) | SIFT tolerated (0.27); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- CYP19A1 | c.1174A>G p.T392A | Missense Mutation (SNP) | VAF 136/445 reads (31%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.917); called by muse, mutect2, varscan2
- FN1 | c.6943G>A p.A2315T (on ENST00000359671 / NM_001365524.2; = p.A2284T on NM_002026.4) | Missense Mutation (SNP) | VAF 160/466 reads (34%) | SIFT tolerated (0.46); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- FNDC3B | c.264G>A p.Q88= | Splice Region (SNP) | VAF 30/113 reads (27%) | called by muse, mutect2, varscan2
- GALNTL5 | c.157C>T p.H53Y | Missense Mutation (SNP) | VAF 22/637 reads (3%) | SIFT tolerated (0.93); PolyPhen benign (0); called by muse, mutect2
- KMT5B | c.1051C>G p.L351V | Missense Mutation (SNP) | VAF 58/217 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- LAMB1 | c.4003G>T p.V1335L | Missense Mutation (SNP) | VAF 110/493 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.103); called by muse, mutect2, varscan2
- LIMK1 | c.1287C>T p.D429= | Splice Region (SNP) | VAF 14/453 reads (3%) | called by muse, mutect2
- MROH2B | c.1371del p.F457Lfs*21 | Frame Shift Del (DEL) | VAF 32/130 reads (25%) | called by pindel, varscan2
- OGFRL1 | c.1021T>G p.S341A | Missense Mutation (SNP) | VAF 89/246 reads (36%) | SIFT tolerated (0.12); PolyPhen benign (0.239); called by muse, mutect2, varscan2
- RXRG | c.88T>C p.S30P | Missense Mutation (SNP) | VAF 57/158 reads (36%) | SIFT tolerated, low confidence (0.13); PolyPhen possibly damaging (0.473); called by muse, mutect2, varscan2
- SEPTIN8 | c.755T>C p.L252P | Missense Mutation (SNP) | VAF 46/218 reads (21%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.588); called by muse, mutect2, varscan2
- SRC | c.1193G>A p.G398E | Missense Mutation (SNP) | VAF 66/204 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SRRM3 | c.1598A>G p.D533G | Missense Mutation (SNP) | VAF 53/235 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.124); called by muse, mutect2, varscan2
- SUSD4 | c.1245_1246insTGCATACCCC p.G416Cfs*19 | Frame Shift Ins (INS) | VAF 36/144 reads (25%) | called by mutect2, varscan2
- TRIM4 | c.805A>T p.K269* | Nonsense Mutation (SNP) | VAF 51/259 reads (20%) | called by muse, mutect2, varscan2
- ZNF34 | c.769G>A p.G257R | Missense Mutation (SNP) | VAF 69/268 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.102); called by muse, mutect2, varscan2
- ZNF484 | c.1792C>T p.H598Y | Missense Mutation (SNP) | VAF 100/255 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- DMGDH | c.2445C>T p.F815= | Silent (SNP) | VAF 119/413 reads (29%) | catalogued as rs549605143, COSV99668772; called by muse, mutect2, varscan2
- FLYWCH1 | c.654G>A p.G218= (on ENST00000253928 / NM_001308068.2; = p.G217= on NM_020912.1 and 1 other RefSeq transcript) | Silent (SNP) | VAF 110/345 reads (32%) | called by muse, mutect2, varscan2
- HEPHL1 | c.2040C>T p.P680= | Silent (SNP) | VAF 66/385 reads (17%) | catalogued as rs775319018; called by muse, mutect2, varscan2
- INSRR | c.2646C>T p.P882= | Silent (SNP) | VAF 79/306 reads (26%) | called by muse, mutect2, varscan2
- KYNU | c.480A>T p.L160= | Silent (SNP) | VAF 44/221 reads (20%) | catalogued as COSV51579261; called by muse, mutect2, varscan2
- NUDCD3 | c.834G>A p.E278= | Silent (SNP) | VAF 11/227 reads (5%) | called by muse, mutect2
- PGR | c.1479C>T p.D493= | Silent (SNP) | VAF 41/102 reads (40%) | catalogued as rs375446843; called by muse, mutect2, varscan2
- SLITRK6 | c.2049G>A p.V683= | Silent (SNP) | VAF 62/268 reads (23%) | catalogued as rs779424776; called by muse, mutect2, varscan2
- TRPM6 | c.258C>T p.H86= | Silent (SNP) | VAF 179/533 reads (34%) | called by muse, mutect2, varscan2
- TUBD1 | c.18G>A p.V6= | Silent (SNP) | VAF 37/88 reads (42%) | catalogued as COSV56674876; called by muse, mutect2, varscan2
- XIRP2 | c.8826C>T p.R2942= (on ENST00000628543; = p.R3117= on NM_152381.6) | Silent (SNP) | VAF 77/301 reads (26%) | catalogued as rs1241155334, COSV54698627; called by muse, mutect2, varscan2
- AOC4P | n.1439C>G | RNA (SNP) | VAF 116/254 reads (46%) | called by muse, mutect2, varscan2
- FAM27E5 | n.415C>T | RNA (SNP) | VAF 50/383 reads (13%) | catalogued as rs768338600; called by muse, mutect2, varscan2
- GRXCR1 | c.-44C>T | 5'UTR (SNP) | VAF 49/135 reads (36%) | catalogued as rs530060375; called by muse, mutect2, varscan2
- HERC2P3 | n.1377+40C>T | Intron (SNP) | VAF 93/613 reads (15%) | catalogued as rs746545872; called by muse, mutect2, varscan2
- MPHOSPH8 | c.2458-241G>A | Intron (SNP) | VAF 39/103 reads (38%) | called by muse, mutect2, varscan2
- MYO1E | c.911-191A>G | Intron (SNP) | VAF 49/184 reads (27%) | catalogued as rs751100967; called by muse, mutect2, varscan2
- N4BP2L2 | chr13:32442593 C>T | 3'Flank (SNP) | VAF 38/126 reads (30%) | catalogued as rs758169870; called by muse, mutect2, varscan2
- PLA2G2A | c.41-39C>T | Intron (SNP) | VAF 39/119 reads (33%) | catalogued as rs767608899; called by muse, mutect2, varscan2
- PSMG4 | c.250+11A>C | Intron (SNP) | VAF 36/138 reads (26%) | called by muse, mutect2, varscan2
- TMEM67 | chr8:93754845 A>G | 5'Flank (SNP) | VAF 21/65 reads (32%) | called by muse, mutect2, varscan2
